Gene-level copy-number profile of tumor specimen TCGA-B6-A408-01A from TCGA case TCGA-B6-A408, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.0 years (20,102 days).
Specimen TCGA-B6-A408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2d33342b-a41f-4bb1-9226-1b5058209488.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A408-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d08bbf8-90b9-44ff-9712-a97ed581bbb2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,294; copy number 2: 4,911; copy number 3: 22,259; copy number 4: 27,662; copy number 5: 1,560; copy number 7: 94; copy number 8: 58; copy number 10: 147; copy number 11: 394; copy number 12: 12; copy number 13: 17; copy number 14: 116; copy number 16: 102; copy number 20: 88; copy number 22: 37; copy number 23: 58; copy number 27: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A408-01A-12D-A242-01): tumor purity 0.57, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 981 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:29,905,735–30,572,256, 23 genes, copy number 14 (within-gene range 1–14): AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS.
- chr8:31,639,222–36,321,404, 53 genes, copy number 10–16 (within-gene range 1–16): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:36,784,324–43,674,591, 176 genes, copy number 10–16 (broad region; genes not listed).
- chr9:25,579,657–30,690,272, 46 genes, copy number 10–14: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2.
- chr12:53,479,669–54,351,846, 60 genes, copy number 14: MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1, CALCOCO1, AC076968.2, CISTR, AC076968.1, RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P.
- chr12:54,353,792–54,466,985, 4 genes, copy number 14 (within-gene range 4–14): AC079313.1, GPR84, ZNF385A, ITGA5.
- chr12:64,222,337–64,397,065, 1 gene, copy number 23 (within-gene range 4–23): AC012158.1.
- chr12:64,264,762–64,390,758, 1 gene, copy number 23 (within-gene range 4–23): C12orf56.
- chr12:64,338,178–71,586,310, 155 genes, copy number 14–23 (broad region; genes not listed).
- chr12:76,858,709–80,937,925, 47 genes, copy number 22–27: CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr13:31,739,526–31,846,539, 2 genes, copy number 12: RXFP2, AL138708.1.
- chr13:31,952,580–31,961,946, 2 genes, copy number 12: EEF1DP3, AC002525.1.
- chr13:32,400,723–32,788,178, 9 genes, copy number 13 (within-gene range 1–13): N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1.
- chr16:28,097,976–28,323,849, 8 genes, copy number 13: XPO6, TPRKBP2, AC136611.1, RNY1P10, GAPDHP35, AC138904.3, SBK1, AC138904.1.
- chr16:29,742,463–35,912,516, 394 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
